Somatic mutation profile of tumor specimen TCGA-MQ-A4LI-01A (aliquot TCGA-MQ-A4LI-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4LI, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 60.1 years (21,951 days).
Specimen TCGA-MQ-A4LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f240f0be-cd56-45e4-bd81-2404253c776f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LI-10A (Blood Derived Normal), aliquot TCGA-MQ-A4LI-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c8929bd-9723-4a58-b666-e29b5ba9429c

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Nonsense Mutation 3, 5'Flank 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF12 | c.4150G>A p.A1384T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760873730; called by muse, mutect2, varscan2
- DNMT3B | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV52417579; called by muse, mutect2, varscan2
- DSCAM | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs762944210, COSV68024878; called by muse, mutect2, varscan2
- GDF10 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs1555207447; called by muse, mutect2, varscan2
- H4C9 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); catalogued as rs761496441; called by muse, mutect2, varscan2
- LDB1 | c.770C>T p.S257L (on ENST00000425280 / NM_001321612.2; = p.S221L on NM_003893.5) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63289211; called by muse, mutect2
- POLN | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs184629020; called by muse, mutect2, varscan2
- RSPH4A | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV57635133; called by muse, mutect2, varscan2
- RYR2 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 35/156 reads (22%) | catalogued as rs1340830020, COSV100773556; called by muse, mutect2, varscan2
- SLIT1 | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99822652; called by muse, mutect2, varscan2
- TM9SF3 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100951854; called by muse, mutect2, varscan2
- UTP20 | c.5755G>A p.G1919R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779982797; called by muse, mutect2, varscan2
- ADM | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADSS2 | c.791-1_797del p.X264_splice | Splice Site (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.4128C>A p.Y1376* (on ENST00000611781; = p.Y1320* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- ASCC3 | c.3775A>T p.I1259F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BBOX1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CCNYL1 | c.950A>G p.E317G (on ENST00000295414 / NM_001330218.2; = p.E247G on NM_152523.2) | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CPNE7 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DBX1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYSL5 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRMD4A | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IFT122 | c.2126C>T p.A709V (on ENST00000348417 / NM_052989.3; = p.A650V on NM_018262.4) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- LAMA4 | c.3234A>T p.E1078D (on ENST00000230538 / NM_001105206.3; = p.E1071D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP4 | c.4704G>A p.W1568* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- OBSCN | c.10123G>C p.E3375Q | Missense Mutation (SNP) | VAF 166/314 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PAWR | c.134del p.G45Afs*45 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, mutect2
- SULT1E1 | c.206G>T p.C69F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE1 | c.14595A>T p.L4865F (on ENST00000367255 / NM_182961.4; = p.L4794F on NM_033071.3) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CFD | c.477G>A p.A159= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- DCC | c.612G>A p.P204= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs144555146; called by muse, mutect2, varscan2
- DNAH8 | c.7584T>C p.P2528= | Silent (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- GBF1 | c.1791C>T p.V597= (on ENST00000369983 / NM_001377137.1; = p.V596= on NM_004193.3) | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- MARK1 | c.1881T>C p.Y627= | Silent (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099591 C>A | 5'Flank (SNP) | VAF 28/138 reads (20%) | catalogued as rs1334081839; called by muse, varscan2
- MUC2 | chr11:1099592 C>A | 5'Flank (SNP) | VAF 29/140 reads (21%) | catalogued as rs1358121890; called by muse, varscan2
